EXCEPTIONAL_RESPONDERS case ER-ABF0 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b324e0ac-b0fd-4d3d-802b-d69e2386a5a9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,042 days); Year of diagnosis: 2008; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 2,429 days (6.7 years); Days to best overall response: 168 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Docetaxel + Trastuzumab; Days to treatment start: 31 days; Days to treatment end: 211 days.

Follow-up (1 entry)
- Days to follow up: 2,429 days (6.7 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 2,429 days (6.7 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABF0-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample ER-ABF0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ABF0-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 4.
